Somatic mutation profile of tumor specimen MP2PRT-PAUNTH-TMP1-A (aliquot MP2PRT-PAUNTH-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUNTH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,398 days).
Specimen MP2PRT-PAUNTH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f2a8431-3211-4e1c-89a1-c4a434dc3619.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNTH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNTH-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27f5fe6a-ea1d-42f5-b2b3-19757182fac6

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 25, Silent 5, In Frame Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 186/449 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs1296032474; called by muse, mutect2, varscan2
- ACTBL2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 43/594 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.195); catalogued as rs1250211202; called by muse, mutect2
- AGRN | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 302/646 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs370516291; called by muse, mutect2, varscan2
- ASNSD1 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 50/714 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs758926939, COSV53624400; called by muse, mutect2
- CAPN10 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 325/636 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs756667300; called by muse, mutect2, varscan2
- COBLL1 | c.1547C>T p.P516L (on ENST00000392717; = p.P478L on NM_014900.5) | Missense Mutation (SNP) | VAF 209/484 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748344045, COSV52071086; called by muse, mutect2, varscan2
- FRY | c.5707G>C p.E1903Q | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV66571751; called by muse, mutect2, varscan2
- GRPR | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 252/329 reads (77%) | catalogued as rs758723725; called by muse, mutect2, varscan2
- LURAP1L | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 183/363 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs139119328; called by muse, mutect2, varscan2
- MYH4 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 294/646 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs574656865, COSV55125692; called by muse, mutect2, varscan2
- NYAP1 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 47/760 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.115); catalogued as COSV55720487; called by muse, mutect2
- PLEKHA8 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs779344389, COSV51649023; called by muse, mutect2, varscan2
- PRSS16 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149942995; called by muse, mutect2, varscan2
- SRGAP1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 197/450 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767868053; called by muse, mutect2, varscan2
- TOPBP1 | c.3781C>G p.H1261D | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV53437560; called by muse, mutect2, varscan2
- AASS | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 167/370 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- BPIFB4 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 181/526 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DOLPP1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 112/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNAR2 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 214/485 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- IGHV3-73 | chr14:106802688 TGTGTGTCTAG>CCCCCC | Missense Mutation (DEL) | VAF 47/239 reads (20%) | called by pindel, varscan2*
- IGLJ7 | c.8_9insGGG p.C3delinsWG | In Frame Ins (INS) | VAF 123/340 reads (36%) | called by mutect2, varscan2
- IGLJ7 | c.9delinsGGGG p.C3delinsWG | In Frame Ins (INS) | VAF 138/398 reads (35%) | called by mutect2*, pindel, varscan2*
- KCNIP4 | c.280T>C p.F94L | Missense Mutation (SNP) | VAF 108/221 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NRG2 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 264/556 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- RAPGEF4 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RIMBP3 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- YEATS2 | c.3307C>G p.P1103A | Missense Mutation (SNP) | VAF 166/401 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF696 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 340/730 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.1632C>T p.I544= | Silent (SNP) | VAF 215/452 reads (48%) | catalogued as COSV99629795; called by muse, mutect2, varscan2
- MRPL11 | c.336G>A p.V112= | Silent (SNP) | VAF 148/499 reads (30%) | called by muse, mutect2, varscan2
- NAGA | c.618G>A p.A206= | Silent (SNP) | VAF 178/400 reads (45%) | catalogued as rs200770245; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PLK3 | c.219C>T p.F73= | Silent (SNP) | VAF 224/554 reads (40%) | catalogued as rs759735743, COSV64728444; called by muse, mutect2, varscan2
- TAS1R1 | c.525G>A p.T175= | Silent (SNP) | VAF 154/339 reads (45%) | catalogued as rs774019433; called by muse, mutect2, varscan2
